Surgical pathology report (de-identified scan), TCGA case TCGA-43-7656, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Christiana Healthcare, specimen TCGA-43-7656-01A (Primary Tumor).

[page 1 of 2]
Diagnosis

A,C,D. Lymph nodes, level 11 and level 7, excisions -
Negative for tumor.

B. Lung, right lower lobe, excision -
Poorly differentiated non-small cell carcinoma, compatible with poorly
differentiated squamous cell carcinoma (see microscopic description).
Margins negative for malignancy.
Hilar and peri-bronchial lymph nodes negative for malignancy.

Microscopic Description:

The following template summarizes the findings in this case:

Histologic type: Poorly differentiated non-small cell carcinoma,
compatible with poorly differentiated squamous cell carcinoma,
comprising the mass lesion in part B. The tumor does not immunostain
for synaptophysin, compatible with this interpretation.
[REDACTED] have reviewed representative slides and concur.

Histologic grade: Poorly differentiated

Primary tumor (pT): pT1b

Margins of resection: Negative

Direct extension of tumor: Not identified. Pleural invasion is not
identified.

Vascular invasion: Not identified

Regional lymph nodes (pN): pN0. The lymph nodes, including the hilar
and peribronchial lymph nodes in part B, as well as the separately
submitted lymph nodes in parts A, C, & D, are negative for tumor.
There is focal hyalinization in lymph nodes, which might reflect old
granulomas. No fungal elements are identified in the hyalinized areas
on silver-stained sections examined in part B.

Distant metastasis (pM): Not applicable

Other findings: The lung away from the tumor has scattered chronic
inflammation and interstitial thickening.

Specimen

- A. Level 11 node
- B. Right lower lobe of lung
- C. Addition level 11 lymph node
- D. Level 7 lymph node

Clinical Information

PRE-OP DIAGNOSIS: Lung CA

Gross Description

- A. Received fresh labeled "level 11 lymph node" are multiple fragmented
soft gray-black-pink tissue fragments, in aggregate 1.4 x 0.8 x 0.3 cm.
AS-1.

[page 2 of 2]
B. Received fresh in a container labeled "right lower lobe of lung" is a 300 g, 19.2 x 17 x 5 cm, lobectomy specimen, with a 1 cm long, 2.7 x 1 cm in cross-section, bronchial stump, which is without focal lesion. The vessels at the margin are also grossly unremarkable. The pleura is smooth to wrinkled red-gray-purple, with a focus of retraction and subjacent induration along the lateral posterior aspect. The pleura overlying the induration is inked blue. The lung is sectioned, revealing a well-circumscribed 2.8 x 2.5 x 2.4 cm rubbery tan-white tumor underlying the aforementioned area, which extends very peripherally, without definite gross pleural involvement. Per the clinical request, a portion of tumor and a portion of normal parenchyma are procured. The parenchyma away from this area is spongy and tan-red, with diffuse black stippling, with other focal lesions. Soft grey-black peribronchial and hilar lymph nodes up to 1 cm in greatest dimension are identified. RS-12, following fixation, according to the accompanying block summary.

BLOCK SUMMARY: 1 - bronchial margin; 2 - vascular margins; 3 -6 - tumor, including relation to pleural surface and to uninvolved lung; 7-9 - lung away from tumor; 10,11- peri-bronchial lymph nodes; 12 - hilar lymph nodes.

C. Received fresh in a container labeled "additional level 11 lymph node" are several fragmented soft tan-gray-red pieces of tissue, in aggregate 2.5 x 2.1 x 0.5 cm. AS-1, following fixation.

D. Received fresh in a container labeled "level 7 lymph node" is a 3.8 x 2.9 x 0.6 cm aggregate of fragmented soft tan-gray-gold tissue and fat. AS-3, following fixation.

Source: NCI Genomic Data Commons file ff706fdd-4967-4ffa-9abd-ce65466fcccb (TCGA-43-7656.57B4E426-72C1-43BA-B8F1-D17CE36E6478.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).